CCDI case PBCMGS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/258e74c6-0f5c-4f4a-83b7-8ba3863e6893

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.7 years (2,067 days).

Biospecimens (2 samples)
- Sample 0DWHZ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWI1A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
